Somatic mutation profile of tumor specimen TCGA-C5-A1BF-01B (aliquot TCGA-C5-A1BF-01B-11D-A13W-08) from TCGA case TCGA-C5-A1BF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 46.5 years (16,975 days).
Specimen TCGA-C5-A1BF-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24e71d86-8fd3-47c4-8441-e6002c899f46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BF-10A (Blood Derived Normal), aliquot TCGA-C5-A1BF-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/301ffbee-4acd-4fcd-b51b-1b2308003a8b

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Nonsense Mutation 5, Frame Shift Ins 3, 5'Flank 2, Splice Site 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs104894333, CM980100, COSV52229600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6088C>T p.R2030W | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1277494907, COSV66066682; called by muse, mutect2, varscan2
- ADAMTS20 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67131891; called by muse, mutect2, varscan2
- ADGRV1 | c.12820G>C p.E4274Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV67985752; called by muse, mutect2, varscan2
- ANKRD30A | c.3673A>T p.I1225F (on ENST00000611781; = p.I1169F on NM_052997.2) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1321258303, COSV64610879; called by muse, mutect2, varscan2
- AXDND1 | c.870G>C p.R290S | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV62642995; called by muse, mutect2, varscan2
- C11orf52 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV53714674; called by muse, mutect2, varscan2
- CBLL1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV56028969; called by muse, mutect2, varscan2
- CEP135 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV57260213, COSV57261443; called by muse, mutect2, varscan2
- CERT1 | c.1962G>A p.W654* (on ENST00000405807 / NM_001130105.1; = p.W526* on NM_005713.3) | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV54659008; called by muse, mutect2, varscan2
- CGA | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63644455, COSV63644955; called by muse, mutect2, varscan2
- DEPDC4 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs993291237, COSV54553671; called by muse, mutect2, varscan2
- DIABLO | c.424G>A p.E142K (on ENST00000443649 / NM_001278303.1; = p.E215K on NM_019887.6) | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928226; called by muse, mutect2
- DOCK10 | c.6162G>C p.M2054I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV51402485; called by muse, mutect2, varscan2
- DST | c.11635G>C p.E3879Q (on ENST00000361203 / NM_001374722.1; = p.E1467Q on NM_015548.5) | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV55015889; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.540G>C p.L180F | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.71); PolyPhen benign (0.291); catalogued as rs1232860201, COSV57516123; called by muse, mutect2, varscan2
- FAT1 | c.1622C>G p.S541* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV71674248; called by muse, mutect2, varscan2
- GALNTL6 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV72552862, COSV72552990; called by muse, mutect2, varscan2
- GLI3 | c.3687G>C p.L1229F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV67888789; called by muse, mutect2, varscan2
- GLRA3 | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV56862234; called by muse, mutect2, varscan2
- HDC | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV51070783; called by muse, mutect2, varscan2
- HSD17B4 | c.1942C>T p.Q648* (on ENST00000414835 / NM_001199291.3; = p.Q623* on NM_000414.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV56335854; called by muse, mutect2, varscan2
- HUWE1 | c.646-1G>C p.X216_splice | Splice Site (SNP) | VAF 15/164 reads (9%) | catalogued as COSV99472510; called by muse, mutect2
- IFNLR1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as rs772253018, COSV59526510; called by muse, mutect2, varscan2
- IQCG | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 31/627 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV54562810; called by muse, mutect2
- ITGAX | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as rs756151867, COSV51645989, COSV51646965; called by muse, mutect2, varscan2
- LAMB2 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV59733717; called by muse, mutect2, varscan2
- MARCHF11 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV60127775; called by muse, mutect2, varscan2
- OLFM3 | c.448A>T p.M150L (on ENST00000338858 / NM_001288821.1; = p.M130L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.456); catalogued as COSV58799033; called by muse, mutect2, varscan2
- PAOX | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV53372555; called by muse, mutect2, varscan2
- PATZ1 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53229521; called by muse, mutect2, varscan2
- PPL | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.782); catalogued as COSV52168117, COSV52168285; called by muse, mutect2, varscan2
- PRG4 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV63355599; called by muse, mutect2, varscan2
- PRG4 | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV63355602; called by muse, mutect2, varscan2
- PRRC2B | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV61937288; called by muse, mutect2, varscan2
- RANBP2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.412); catalogued as COSV51701527; called by muse, mutect2, varscan2
- RFFL | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV52071781; called by muse, mutect2, varscan2
- RNF186 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs199500273, COSV100909102; called by muse, mutect2, varscan2
- SERPINB6 | c.346G>A p.E116K (on ENST00000612421 / NM_001271823.2; = p.E97K on NM_004568.6) | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59565855; called by muse, mutect2, varscan2
- SIRT6 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1259485520, COSV50199024; called by muse, mutect2, varscan2
- SLC30A6 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50872565; called by muse, mutect2, varscan2
- SLITRK5 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753443574, COSV61523040, COSV61523200; called by muse, mutect2, varscan2
- SYT7 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55655949; called by muse, mutect2, varscan2
- TGM4 | c.1410G>C p.E470D | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV56094012, COSV56094021; called by muse, mutect2, varscan2
- TNKS | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60058202; called by muse, mutect2, varscan2
- TRPA1 | c.3052C>T p.H1018Y | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs780432819, COSV51562313; called by muse, mutect2, varscan2
- ZNF283 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV61031331; called by muse, mutect2, varscan2
- ABR | c.640del p.E214Nfs*4 (on ENST00000302538 / NM_021962.5; = p.E177Nfs*4 on NM_001092.5) | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- FAT1 | c.7523dup p.H2508Qfs*27 | Frame Shift Ins (INS) | VAF 111/437 reads (25%) | called by mutect2, pindel, varscan2
- NF2 | c.115-3_118del p.X39_splice | Splice Site (DEL) | VAF 35/84 reads (42%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.6052_6053insT p.H2018Lfs*9 | Frame Shift Ins (INS) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- STK11 | c.149_156dup p.D53* | Frame Shift Ins (INS) | VAF 14/27 reads (52%) | called by mutect2, varscan2
- ADGRE5 | c.744G>A p.P248= (on ENST00000242786 / NM_078481.4; = p.P155= on NM_001784.5) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1278712974; called by mutect2, varscan2
- C2orf49 | c.30C>T p.C10= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51527867; called by muse, mutect2
- CLCN1 | c.1632G>T p.V544= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV58370091; called by muse, mutect2, varscan2
- CNNM1 | c.1473C>T p.D491= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV63201729; called by muse, mutect2, varscan2
- DNAH3 | c.7359C>T p.Y2453= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs771844759, COSV54523858; called by muse, mutect2, varscan2
- GRIN3B | c.2364C>T p.S788= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs571283387, COSV52260513; called by mutect2, varscan2
- IQGAP3 | c.381G>A p.T127= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as rs138994698; called by muse, mutect2, varscan2
- LAMB2 | c.4320C>G p.L1440= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV59733706; called by muse, mutect2, varscan2
- NEB | c.60C>T p.Y20= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as rs768163455, COSV51419097; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA9 | c.132C>T p.F44= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as COSV65323991; called by muse, mutect2, varscan2
- PGBD5 | c.570G>A p.L190= (on ENST00000525115; = p.L259= on NM_001258311.2) | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV58411854, COSV58412880; called by muse, mutect2, varscan2
- PHKG2 | c.1173A>C p.G391= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as COSV60312081; called by muse, mutect2
- POLR3E | c.1992C>G p.R664= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV55400803; called by muse, mutect2, varscan2
- PPP2R1B | c.300T>C p.C100= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV59535654; called by muse, mutect2, varscan2
- PXN | c.1545C>T p.F515= (on ENST00000228307 / NM_001080855.3; = p.F481= on NM_002859.4) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs759575217, COSV57218902; called by muse, mutect2, varscan2
- ZFYVE26 | c.1824G>A p.K608= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV61328750; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498599 C>T | 5'Flank (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- GLOD4 | chr17:783173 C>G | 5'Flank (SNP) | VAF 24/98 reads (24%) | catalogued as rs1226351620, COSV100022582; called by muse, mutect2, varscan2
- TTN | c.10360+4910A>G | Intron (SNP) | VAF 54/120 reads (45%) | catalogued as COSV60080951; called by muse, mutect2, varscan2
